Somatic mutation profile of tumor specimen TCGA-IB-AAUO-01A (aliquot TCGA-IB-AAUO-01A-12D-A38G-08) from TCGA case TCGA-IB-AAUO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.7 years (23,622 days).
Specimen TCGA-IB-AAUO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab17e6bd-08b1-492e-9d87-e81d3548efeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUO-10A (Blood Derived Normal), aliquot TCGA-IB-AAUO-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/078fa258-be00-4c54-a70b-79f0b63751ad

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 27, Silent 13, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/316 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.3551-1G>C p.X1184_splice | Splice Site (SNP) | VAF 37/292 reads (13%) | catalogued as rs759235937, COSV99272712; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138636937; called by muse, mutect2, varscan2
- ADGRD1 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 28/1125 reads (2%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99895512; called by muse, mutect2
- BCL11A | c.1016C>T p.P339L (on ENST00000335712 / NM_001365609.1; = p.P373L on NM_018014.4) | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs777891691, COSV59638393, COSV59638435; called by muse, mutect2, varscan2
- BRCA1 | c.1936A>G p.S646G | Missense Mutation (SNP) | VAF 61/597 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as CD125440, COSV100524206; called by muse, mutect2, varscan2
- C10orf82 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100980107; called by muse, mutect2, varscan2
- CHGA | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.337); catalogued as COSV99381139; called by muse, mutect2
- DYNC2H1 | c.3745G>T p.D1249Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV100518620, COSV100519289; called by mutect2, varscan2
- EFTUD2 | c.2867C>A p.P956H | Missense Mutation (SNP) | VAF 89/648 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1340884778, COSV99493954; called by muse, mutect2, varscan2
- FLNC | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs776881635, COSV57950302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRID2 | c.2294T>G p.V765G | Missense Mutation (SNP) | VAF 23/593 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99941009; called by muse, mutect2
- KIAA1217 | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 41/200 reads (21%) | catalogued as COSV100286671; called by muse, mutect2, varscan2
- KIRREL3 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as COSV101585732; called by muse, mutect2, varscan2
- KRT24 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1010075674, COSV99232030; called by muse, mutect2
- LPO | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228823; called by muse, mutect2, varscan2
- MRPS33 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.8); catalogued as rs369862542; called by muse, mutect2, varscan2
- NFKBIZ | c.1888del p.R630Afs*13 | Frame Shift Del (DEL) | VAF 44/382 reads (12%) | catalogued as COSV58199654; called by pindel, varscan2
- PHLDB2 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 160/451 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101208532; called by muse, mutect2, varscan2
- PLXNA2 | c.1588T>C p.W530R | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100885503; called by muse, mutect2
- PREPL | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 125/774 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs774922740, COSV53215253; called by muse, mutect2, varscan2
- RECQL | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 70/458 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100131272; called by mutect2, varscan2
- SEL1L | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 46/1335 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377903; called by muse, mutect2
- SERPINB10 | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.09); catalogued as COSV99449209; called by muse, mutect2, varscan2
- SGCD | c.95G>A p.R32Q (on ENST00000435422 / NM_001128209.2; = p.R33Q on NM_000337.5) | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1488623227, COSV61903603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC47A1 | c.658A>G p.N220D | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV99565333; called by muse, mutect2, varscan2
- TDRD5 | c.1420G>T p.G474W | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174691297, COSV99676291, COSV99676678; called by muse, mutect2, varscan2
- VPS25 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 98/727 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs779826927, COSV99519426; called by muse, mutect2, varscan2
- WDR48 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100176579; called by muse, mutect2, varscan2
- WWP2 | c.1970G>A p.W657* | Nonsense Mutation (SNP) | VAF 87/460 reads (19%) | catalogued as COSV100598562; called by muse, mutect2, varscan2
- ZDBF2 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100984917; called by muse, mutect2, varscan2
- AHCTF1 | c.3944dup p.L1316Pfs*5 (on ENST00000366508; = p.L1290Pfs*5 on NM_015446.5) | Frame Shift Ins (INS) | VAF 44/394 reads (11%) | called by mutect2, pindel, varscan2
- ERCC6L | c.1081dup p.L361Pfs*6 | Frame Shift Ins (INS) | VAF 132/686 reads (19%) | called by mutect2, pindel, varscan2
- ACSM4 | c.759C>T p.C253= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs200562081; called by muse, mutect2
- ARHGAP20 | c.2595A>G p.S865= | Silent (SNP) | VAF 109/600 reads (18%) | catalogued as COSV99504090; called by muse, mutect2, varscan2
- ARID3C | c.1122C>T p.N374= | Silent (SNP) | VAF 46/381 reads (12%) | catalogued as rs563083593, COSV52406973; called by muse, mutect2, varscan2
- CDHR3 | c.2541G>A p.A847= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as rs1297175574, COSV58420962; called by muse, mutect2
- COL5A1 | c.4191C>T p.P1397= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1173806309, COSV100879974; called by muse, mutect2, varscan2
- COQ3 | c.201C>T p.I67= | Silent (SNP) | VAF 24/830 reads (3%) | catalogued as COSV54642426, COSV99632720; called by muse, mutect2
- DIP2C | c.2415C>T p.N805= | Silent (SNP) | VAF 63/346 reads (18%) | catalogued as rs768099475, COSV99791772; called by muse, mutect2, varscan2
- GREB1 | c.5835G>A p.T1945= | Silent (SNP) | VAF 36/398 reads (9%) | catalogued as rs376089071; ClinVar: likely benign; called by muse, mutect2
- MBD3L1 | c.384G>A p.A128= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs765959320, COSV99977993; called by muse, mutect2, varscan2
- PKD2L1 | c.909C>T p.I303= | Silent (SNP) | VAF 41/356 reads (12%) | catalogued as rs754383648, COSV100559380; called by muse, mutect2, varscan2
- PSG3 | c.441C>A p.P147= | Silent (SNP) | VAF 166/981 reads (17%) | catalogued as COSV100548596; called by muse, mutect2, varscan2
- WSCD1 | c.1587G>A p.R529= | Silent (SNP) | VAF 65/248 reads (26%) | catalogued as rs1204500348, COSV100496583; called by muse, mutect2, varscan2
- ZNF667 | c.1323A>G p.K441= | Silent (SNP) | VAF 12/486 reads (2%) | catalogued as COSV99410465; called by muse, mutect2
